Surgical pathology report (de-identified scan), TCGA case TCGA-HT-7875, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Case Western - St Joes, specimen TCGA-HT-7875-01A (Primary Tumor).

Tumor Identifier: [REDACTED]
Normal Identifier: [REDACTED]

Microscopic Description:

Sections demonstrate a mildly to moderately hypercellular glial neoplasm composed of cells with round mildly enlarged nuclei and prominent perinuclear halos. The tumor diffusely infiltrates both gray and white matter. No mitotic figures are identified in 25 high-power fields examined. Neither microvascular proliferation nor necrosis are present.

Addendum Discussion:

A few scattered MIB-1 reactive cells are present. The labeling index is 1.1%, indicative a modestly proliferative neoplasm and consistent with the low grade histologic features.

Diagnosis:

Low-grade Oligiodendroglioma (who grade II)
MIB-1 Labeling Index= 1.2%

Source: NCI Genomic Data Commons file 3f59c384-588c-42bb-9061-69a33977daf5 (TCGA-HT-7875.F247C5BA-6D4D-4D31-B3C5-C0DFC3211E9D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).